Somatic mutation profile of tumor specimen TCGA-L5-A8NV-01A (aliquot TCGA-L5-A8NV-01A-11D-A37C-09) from TCGA case TCGA-L5-A8NV, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage IIA; Tumor grade: G3; Age at diagnosis: 75.4 years (27,546 days).
Specimen TCGA-L5-A8NV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fde1284f-d805-4147-ab27-f18843fe6d1b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-L5-A8NV-11A (Solid Tissue Normal), aliquot TCGA-L5-A8NV-11A-11D-A37F-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b15ae052-7cf7-435f-99b7-2e4445eaceef

The open-access MAF lists 124 somatic variants for this specimen: 91 protein-altering or splice-affecting, 30 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 78, Silent 30, Nonsense Mutation 5, Frame Shift Del 3, Splice Site 2, Splice Region 2, Intron 2, In Frame Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.586C>T p.R196* | Nonsense Mutation (SNP) | VAF 13/53 reads (25%) | hotspot (GDC flag); catalogued as rs397516435, CM941329, COSV52663748, COSV53125285, COSV53128268; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 4/23 reads (17%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCC5 | c.3364G>A p.G1122R | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.532); catalogued as rs745507480, COSV55588561, COSV99656739; called by muse, mutect2, varscan2
- ADARB2 | c.262C>T p.R88W | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.009); catalogued as rs773296233; called by muse, varscan2
- ARVCF | c.484G>A p.A162T | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1234609292; called by muse, mutect2, varscan2
- ATP1A2 | c.2288G>A p.R763H | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1403515889, CM041248, COSV63402674; called by muse, mutect2, varscan2
- ATXN7L2 | c.1192C>T p.P398S | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs1223921736; called by muse, mutect2, varscan2
- BACE2 | c.1547G>A p.R516H | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs753853665, COSV57737948; called by muse, varscan2
- CD177 | c.434G>A p.G145E | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT tolerated (0.39); PolyPhen benign (0.021); catalogued as COSV65121473; called by muse, mutect2, varscan2
- CDH12 | c.1676G>A p.R559H | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as rs763451842, COSV66399245; called by muse, mutect2, varscan2
- COL11A1 | c.3847G>A p.E1283K | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.98); catalogued as COSV100617686; called by muse, mutect2, varscan2
- CPSF2 | c.916C>T p.R306C | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs376230933; called by muse, mutect2, varscan2
- CYFIP2 | c.1469C>T p.T490M | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as rs1478391225, COSV59035624; called by muse, mutect2
- DACH2 | c.1684G>A p.D562N | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT deleterious (0.05); PolyPhen benign (0.089); catalogued as COSV64162542; called by muse, mutect2, varscan2
- DISC1 | c.2448G>T p.Q816H | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV64103467, COSV64127008; called by muse, mutect2, varscan2
- ELAVL2 | c.818G>A p.G273E | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.071); catalogued as COSV56362310; called by muse, mutect2, varscan2
- FAM227B | c.1442_1445del p.R481Nfs*33 | Frame Shift Del (DEL) | VAF 7/52 reads (13%) | catalogued as rs762888521; called by mutect2, pindel, varscan2
- FAM47C | c.1930C>A p.P644T | Missense Mutation (SNP) | VAF 106/180 reads (59%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.712); catalogued as COSV63724537; called by muse, mutect2, varscan2
- FOXG1 | c.1075G>A p.A359T | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.027); catalogued as COSV57397703; called by muse, mutect2, varscan2
- FOXJ1 | c.830C>T p.P277L | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.031); catalogued as rs1351956108; called by muse, mutect2, varscan2
- GDF2 | c.647G>A p.R216Q | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.614); catalogued as rs782493786; called by muse, mutect2, varscan2
- GRIK4 | c.2101G>A p.V701M | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs983325753, COSV70808379; called by muse, mutect2, varscan2
- HELZ2 | c.193G>A p.A65T | Missense Mutation (SNP) | VAF 32/94 reads (34%) | SIFT tolerated (0.22); PolyPhen benign (0.015); catalogued as rs374328737; called by muse, mutect2, varscan2
- KLK15 | c.440C>T p.S147F | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.575); catalogued as COSV56826129; called by muse, mutect2, varscan2
- KRTAP10-7 | c.925G>A p.V309M | Missense Mutation (SNP) | VAF 6/125 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.039); catalogued as rs1453511557, COSV59113598; called by muse, mutect2
- MXRA5 | c.2044C>T p.R682C | Missense Mutation (SNP) | VAF 16/26 reads (62%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.764); catalogued as rs768847893, COSV54231645; called by muse, varscan2
- OBSL1 | c.1406C>T p.P469L | Missense Mutation (SNP) | VAF 38/67 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs996195414; called by muse, mutect2, varscan2
- OR11H12 | c.151G>A p.A51T | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs1316411648, COSV73543452; called by muse, mutect2, varscan2
- PCDH11X | c.16G>T p.G6W | Missense Mutation (SNP) | VAF 35/63 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV53470362, COSV53501091; called by muse, mutect2, varscan2
- PCDHA1 | c.1691C>T p.A564V | Missense Mutation (SNP) | VAF 28/128 reads (22%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.001); catalogued as COSV65376184; called by muse, mutect2, varscan2
- PCDHGA3 | c.1537G>A p.V513I | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.063); catalogued as rs575051330, COSV53909842; called by muse, mutect2, varscan2
- PCSK4 | c.1619C>T p.S540F | Missense Mutation (SNP) | VAF 26/126 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs759518526, COSV56301013; called by muse, varscan2
- PLEKHH2 | c.3055G>T p.E1019* | Nonsense Mutation (SNP) | VAF 3/32 reads (9%) | catalogued as COSV56752071; called by muse, mutect2
- PSG1 | c.851C>T p.P284L | Missense Mutation (SNP) | VAF 51/222 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.862); catalogued as rs769714836, COSV99740679; called by muse, mutect2, varscan2
- PTPRD | c.1258G>T p.A420S | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.517); catalogued as rs1412991544, COSV61933783, COSV61941925; called by muse, mutect2, varscan2
- RBM33 | c.1939C>T p.P647S | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.359); catalogued as COSV56636340; called by muse, mutect2, varscan2
- RBMXL2 | c.128G>A p.R43Q | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as rs766285640, COSV60979748; called by muse, mutect2, varscan2
- SETBP1 | c.2572G>A p.E858K | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1178702025, COSV56312188; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SIGLEC6 | c.653C>T p.T218M | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.068); catalogued as rs368576884; called by muse, mutect2, varscan2
- SLC9A3 | c.1466C>T p.S489L | Missense Mutation (SNP) | VAF 34/75 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.875); catalogued as rs761904648; called by muse, mutect2, varscan2
- SOGA3 | c.1819G>A p.E607K | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV64106017; called by muse, mutect2, varscan2
- SPATA31D1 | c.2969C>A p.S990Y | Missense Mutation (SNP) | VAF 35/93 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.891); catalogued as COSV61201387; called by muse, mutect2, varscan2
- SPN | c.1055G>T p.R352L | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.782); catalogued as rs541956371, COSV100788670; called by muse, mutect2, varscan2
- TDRD5 | c.972+3_972+6del p.X324_splice | Splice Site (DEL) | VAF 11/78 reads (14%) | catalogued as rs746232955; called by mutect2, pindel, varscan2
- TEKT3 | c.625G>A p.D209N | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.426); catalogued as COSV58625981, COSV58627813; called by muse, mutect2, varscan2
- TRIM31 | c.128T>C p.I43T | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT tolerated (0.47); PolyPhen benign (0.009); catalogued as rs770138237; called by muse, mutect2, varscan2
- UBR4 | c.6197C>T p.S2066L | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as rs756294693; called by muse, mutect2, varscan2
- ZNF114 | c.496G>T p.D166Y | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.288); catalogued as COSV59945090; called by muse, mutect2
- ACACA | c.3726C>A p.N1242K | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.71); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- ALG12 | c.769-1G>A p.X257_splice | Splice Site (SNP) | VAF 8/31 reads (26%) | called by muse, mutect2, varscan2
- CENPE | c.4594G>A p.E1532K | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.36); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CHD3 | c.1370A>T p.E457V | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- CYP2C8 | c.993del p.I331Mfs*21 | Frame Shift Del (DEL) | VAF 10/60 reads (17%) | called by mutect2, varscan2
- DMWD | c.424C>T p.R142C | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.586); called by muse, mutect2, varscan2
- ECSIT | c.1100del p.Q367Rfs*107 | Frame Shift Del (DEL) | VAF 5/67 reads (7%) | called by mutect2, pindel
- FSTL4 | c.1766C>A p.P589H | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- GALNT3 | c.1850C>T p.S617L | Missense Mutation (SNP) | VAF 22/38 reads (58%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GRAMD4 | c.440G>T p.G147V | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (0.43); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- HPS1 | c.667A>G p.S223G | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- IGDCC3 | c.1241G>T p.R414M | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- KCNN2 | c.1585A>C p.S529R (on ENST00000264773; = p.S741R on NM_021614.4) | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- KIT | c.2809T>C p.S937P | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.649); called by muse, mutect2, varscan2
- KRTAP19-6 | c.14G>A p.G5D | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- KRTAP2-4 | c.152C>T p.T51M | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- LRRIQ1 | c.2956G>T p.G986C | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAP9 | c.1411G>A p.A471T | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MAST1 | c.1637A>G p.Q546R | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); called by muse, mutect2, varscan2
- MFSD6 | c.190A>T p.I64L | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT deleterious (0.05); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MUC16 | c.34528T>C p.S11510P | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- NID1 | c.2090G>C p.C697S | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- NRXN1 | c.4176A>C p.E1392D | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NXPH4 | c.28T>A p.L10M | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.586); called by muse, mutect2, varscan2
- OTUB2 | c.84C>A p.Y28* | Nonsense Mutation (SNP) | VAF 9/37 reads (24%) | called by muse, mutect2, varscan2
- PON3 | c.798A>C p.L266F | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- PSG3 | c.646G>T p.E216* | Nonsense Mutation (SNP) | VAF 62/217 reads (29%) | called by muse, mutect2, varscan2
- PTCHD1 | c.1181C>T p.T394M | Missense Mutation (SNP) | VAF 18/31 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PTCHD4 | c.296G>T p.S99I | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- RELL2 | c.451G>A p.E151K | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- RITA1 | c.248C>T p.T83I | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.494); called by muse, mutect2, varscan2
- RPTOR | c.622C>T p.Q208* | Nonsense Mutation (SNP) | VAF 8/45 reads (18%) | called by muse, mutect2, varscan2
- SHTN1 | c.689A>G p.K230R | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- SLC44A5 | c.1016T>C p.V339A | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.393); called by muse, mutect2, varscan2
- SLC4A7 | c.1240G>C p.V414L | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.34); PolyPhen benign (0.147); called by muse, mutect2
- STAT3 | c.1107C>T p.D369= | Splice Region (SNP) | VAF 8/50 reads (16%) | called by muse, mutect2, varscan2
- TDRD9 | c.1352C>T p.S451F | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TMEM134 | c.520_522del p.F174del | In Frame Del (DEL) | VAF 11/68 reads (16%) | called by mutect2, pindel, varscan2
- TMEM86A | c.285T>C p.H95= | Splice Region (SNP) | VAF 17/57 reads (30%) | called by muse, mutect2, varscan2
- TXNRD2 | c.1073G>T p.G358V | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- YWHAG | c.589G>T p.A197S | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZNF18 | c.283G>A p.G95R | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.546); called by muse, mutect2, varscan2
- ZNF470 | c.1423C>A p.H475N | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADAMTSL3 | c.2373G>A p.T791= | Silent (SNP) | VAF 4/25 reads (16%) | catalogued as rs773737016, COSV54444093, COSV99720159; called by muse, mutect2
- ARHGAP31 | c.525G>A p.A175= | Silent (SNP) | VAF 14/66 reads (21%) | catalogued as rs1304654063, COSV51791446; called by muse, mutect2, varscan2
- C1orf53 | c.159G>A p.A53= | Silent (SNP) | VAF 8/40 reads (20%) | called by muse, mutect2, varscan2
- CNTN2 | c.2376C>T p.N792= | Silent (SNP) | VAF 23/55 reads (42%) | called by muse, mutect2, varscan2
- COMMD9 | c.183C>T p.L61= | Silent (SNP) | VAF 6/27 reads (22%) | called by muse, mutect2
- CSK | c.1137C>T p.I379= | Silent (SNP) | VAF 3/35 reads (9%) | called by muse, mutect2
- FLNC | c.4812G>A p.P1604= | Silent (SNP) | VAF 15/27 reads (56%) | catalogued as rs553400393; called by muse, varscan2
- ITGA1 | c.120C>T p.S40= | Silent (SNP) | VAF 7/43 reads (16%) | catalogued as rs768778866; called by muse, mutect2, varscan2
- LYPLAL1 | c.39C>T p.I13= | Silent (SNP) | VAF 12/33 reads (36%) | catalogued as rs372613753; called by muse, mutect2, varscan2
- MED24 | c.1092C>T p.L364= | Silent (SNP) | VAF 18/68 reads (26%) | called by muse, mutect2, varscan2
- MFSD6L | c.96G>A p.P32= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as COSV61003816; called by muse, mutect2
- MYLK | c.4269G>A p.T1423= | Silent (SNP) | VAF 22/63 reads (35%) | catalogued as rs574785619, COSV100659552; ClinVar: likely benign; called by muse, mutect2, varscan2
- PCDH15 | c.1734T>G p.T578= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as COSV57359628; called by muse, mutect2, varscan2
- PCDHB6 | c.1590C>T p.G530= | Silent (SNP) | VAF 59/203 reads (29%) | catalogued as COSV50692466; called by muse, mutect2, varscan2
- PLAUR | c.216G>A p.K72= | Silent (SNP) | VAF 20/72 reads (28%) | called by muse, mutect2, varscan2
- PPP1R3C | c.291G>T p.A97= | Silent (SNP) | VAF 14/51 reads (27%) | called by muse, mutect2, varscan2
- PPP6R1 | c.2184A>C p.R728= | Silent (SNP) | VAF 27/92 reads (29%) | catalogued as rs937235798; called by muse, mutect2, varscan2
- PTCD1 | c.1206G>A p.P402= | Silent (SNP) | VAF 23/70 reads (33%) | catalogued as rs777168916, COSV52867727; called by muse, mutect2, varscan2
- SLC25A17 | c.654G>A p.T218= | Silent (SNP) | VAF 11/31 reads (35%) | catalogued as rs771703211; called by muse, mutect2, varscan2
- SPEF2 | c.4593G>A p.E1531= | Silent (SNP) | VAF 15/41 reads (37%) | called by muse, mutect2, varscan2
- STAB1 | c.5760G>A p.P1920= | Silent (SNP) | VAF 11/24 reads (46%) | catalogued as rs200924394, COSV58731543; called by muse, mutect2, varscan2
- STT3A | c.1635C>T p.N545= | Silent (SNP) | VAF 17/70 reads (24%) | called by muse, mutect2, varscan2
- TAS2R16 | c.663G>A p.A221= | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as rs150899693, COSV50797267; called by muse, mutect2, varscan2
- TENM3 | c.678G>T p.L226= | Silent (SNP) | VAF 24/82 reads (29%) | called by muse, mutect2, varscan2
- TEX15 | c.7524G>A p.A2508= (on ENST00000256246; = p.A2891= on NM_001350162.2) | Silent (SNP) | VAF 8/33 reads (24%) | catalogued as rs753887605; called by muse, mutect2, varscan2
- TTC39B | c.228G>A p.L76= | Silent (SNP) | VAF 10/38 reads (26%) | called by muse, mutect2, varscan2
- TTN | c.84127C>T p.L28043= (on ENST00000591111; = p.L20619= on NM_003319.4) | Silent (SNP) | VAF 13/26 reads (50%) | called by muse, mutect2, varscan2
- USP39 | c.1599G>A p.Q533= | Silent (SNP) | VAF 18/55 reads (33%) | called by muse, mutect2, varscan2
- ZAN | c.5274G>A p.V1758= | Silent (SNP) | VAF 20/67 reads (30%) | catalogued as rs1486109322; called by muse, mutect2, varscan2
- ZNF471 | c.894C>T p.A298= | Silent (SNP) | VAF 17/58 reads (29%) | called by muse, mutect2, varscan2
- ATP2B1 | c.3351+403A>C | Intron (SNP) | VAF 4/32 reads (13%) | called by muse, mutect2
- SYTL2 | c.1615+1293A>G | Intron (SNP) | VAF 7/64 reads (11%) | called by muse, mutect2, varscan2
- TMEM132E | chr17:34579258 G>A | 5'Flank (SNP) | VAF 10/37 reads (27%) | catalogued as rs1365764682; called by muse, mutect2, varscan2
